CCDI case PBCBVS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b5a82172-9c9e-4b22-bf7a-3000aa33191d

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 12.8 years (4,683 days).

Biospecimens (3 samples)
- Sample 0DNMA4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNMAJ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNMAU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
